Somatic mutation profile of tumor specimen MBCProject_1186_T1_WES (aliquot MBCProject_1186_T1_WES_1) from CMI case MBCProject_1186, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 23.3 years (8,493 days).
Specimen MBCProject_1186_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19866249-f17b-4126-92e3-b690732bcf69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1186_SALIVA (Saliva), aliquot MBCProject_1186_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b012d7b-0a1d-4c98-9266-8b190aea1cd9

The open-access MAF lists 81 somatic variants for this specimen: 50 protein-altering or splice-affecting, 22 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 22, Intron 6, Frame Shift Ins 4, Frame Shift Del 2, Nonsense Mutation 2, 3'UTR 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGT | c.1290dup p.E431* | Frame Shift Ins (INS) | VAF 30/168 reads (18%) | catalogued as rs387906578; ClinVar: pathogenic; called by mutect2, varscan2
- ADAMTS12 | c.4088G>A p.R1363H | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs137953508, COSV100710198; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3230G>T p.R1077L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs758805875, COSV101001040; called by muse, mutect2, varscan2
- ANO1 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 35/744 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs375072440; called by muse, mutect2
- ATP10A | c.4276del p.L1426Cfs*66 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as rs768534594; called by mutect2, pindel, varscan2
- ATP2B3 | c.2768G>A p.R923H | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs201753621, COSV54851969; called by muse, mutect2, varscan2
- BEND7 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 54/290 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.017); catalogued as rs1049327359; called by muse, mutect2, varscan2
- CBFA2T3 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1423013656; called by muse, mutect2, varscan2
- CPXM2 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.545); catalogued as rs529727115, COSV53863911; called by muse, mutect2, varscan2
- CRB1 | c.4005C>T p.D1335= | Splice Region (SNP) | VAF 30/203 reads (15%) | catalogued as rs563910772, COSV66330689; called by muse, varscan2
- CUBN | c.10837C>A p.R3613S | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV64722089; called by muse, mutect2, varscan2
- FNBP4 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as COSV55451618; called by muse, mutect2, varscan2
- FRMD7 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs779971174; called by muse, mutect2
- GATA3 | c.1275dup p.S426Ifs*81 | Frame Shift Ins (INS) | VAF 134/582 reads (23%) | catalogued as COSV60519172, COSV60519754; called by mutect2, pindel, varscan2
- GRIN3B | c.2821G>A p.A941T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1311231682; called by muse, mutect2, varscan2
- IQGAP3 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs148959897, COSV63250601; called by muse, varscan2
- MATN1 | c.649del p.Q217Rfs*39 | Frame Shift Del (DEL) | VAF 40/78 reads (51%) | catalogued as COSV65650320; called by mutect2, pindel, varscan2
- MYO15B | c.5392C>T p.R1798C | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as rs761236514; called by muse, mutect2, varscan2
- MYO16 | c.139A>G p.R47G | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs748245730; called by muse, mutect2, varscan2
- NCR3 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 25/259 reads (10%) | catalogued as rs1280852176, COSV53002558; called by muse, mutect2
- PCBP2 | c.524dup p.K176Efs*46 | Frame Shift Ins (INS) | VAF 29/172 reads (17%) | catalogued as rs776329515; called by mutect2, varscan2
- PDE4B | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs751520439; called by muse, mutect2, varscan2
- PITPNM1 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256171202, COSV62709449; called by muse, mutect2, varscan2
- PPM1J | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs113935705; called by muse, mutect2, varscan2
- PTPRH | c.3109C>T p.L1037F | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779888290, COSV54744932; called by muse, mutect2, varscan2
- RYR3 | c.6940C>T p.R2314C (on ENST00000389232; = p.R2315C on NM_001036.6) | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63109789; called by muse, mutect2, varscan2
- SLC35D2 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779243413, COSV53564198, COSV99480572; called by muse, mutect2, varscan2
- TEAD4 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as COSV63282589; called by muse, mutect2, varscan2
- TSPAN2 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65690080; called by muse, mutect2, varscan2
- AC008676.3 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- APOB | c.9271G>T p.A3091S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- COG2 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- FCRL3 | c.1772C>A p.A591D | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- GBA3 | c.457T>G p.F153V | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- GMCL2 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- IGSF10 | c.4282A>C p.S1428R | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCNA5 | c.429C>A p.N143K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- KDM7A | c.2748dup p.G917Rfs*14 | Frame Shift Ins (INS) | VAF 14/106 reads (13%) | called by mutect2, varscan2
- NEUROD4 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- NUP210L | c.5520A>C p.Q1840H | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR6C1 | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PDS5B | c.4192C>A p.Q1398K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.021); called by muse, mutect2
- PGBD2 | c.994A>T p.I332L | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC36A3 | c.1265A>G p.E422G | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SMOC1 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPAG9 | c.3329C>G p.S1110C (on ENST00000262013 / NM_001130528.3; = p.S1096C on NM_003971.6) | Missense Mutation (SNP) | VAF 69/551 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA46 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 42/246 reads (17%) | called by muse, mutect2, varscan2
- STRC | c.4054C>A p.L1352M | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); called by muse, mutect2
- TEAD3 | c.1205G>A p.S402N | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF653 | c.116T>G p.L39R | Missense Mutation (SNP) | VAF 56/260 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C19orf12 | c.174C>T p.G58= (on ENST00000392278 / NM_001031726.3; = p.G47= on NM_031448.6) | Silent (SNP) | VAF 37/210 reads (18%) | called by muse, mutect2, varscan2
- CACNA1A | c.5538C>T p.P1846= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs754521399; called by muse, varscan2
- CCDC168 | c.20013G>A p.L6671= | Silent (SNP) | VAF 82/170 reads (48%) | called by muse, mutect2, varscan2
- CD5L | c.864G>T p.G288= | Silent (SNP) | VAF 57/339 reads (17%) | catalogued as COSV63822870, COSV63823296; called by muse, mutect2, varscan2
- CYP21A2 | c.1191G>C p.T397= | Silent (SNP) | VAF 26/485 reads (5%) | catalogued as COSV64484917; called by muse, mutect2
- DGKG | c.2193C>A p.A731= | Silent (SNP) | VAF 24/139 reads (17%) | catalogued as COSV53969734; called by muse, mutect2, varscan2
- DOCK6 | c.2004G>A p.R668= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as rs1385798118; called by muse, mutect2, varscan2
- INCENP | c.1542C>T p.S514= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs1415512841, COSV53916180; called by muse, mutect2, varscan2
- MYH2 | c.396G>T p.L132= | Silent (SNP) | VAF 39/227 reads (17%) | called by muse, mutect2, varscan2
- NHLH1 | c.63G>A p.S21= | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as rs1309015465, COSV57483110; called by muse, mutect2, varscan2
- OSBPL9 | c.1485G>A p.V495= | Silent (SNP) | VAF 44/86 reads (51%) | called by muse, mutect2, varscan2
- PMS2 | c.489T>C p.F163= | Silent (SNP) | VAF 47/260 reads (18%) | called by muse, mutect2, varscan2
- PRDM13 | c.1992C>T p.D664= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs546224169, COSV65030423; called by muse, mutect2, varscan2
- RNF20 | c.534G>A p.V178= | Silent (SNP) | VAF 37/186 reads (20%) | catalogued as rs1165175090; called by muse, mutect2, varscan2
- SEC14L3 | c.1161C>T p.D387= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs116181219, COSV53181199; called by muse, mutect2, varscan2
- SPAG17 | c.5565G>A p.T1855= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs150806134; called by muse, mutect2, varscan2
- SRRM2 | c.2028A>G p.R676= | Silent (SNP) | VAF 98/344 reads (28%) | called by muse, mutect2, varscan2
- TDRD5 | c.2274C>A p.A758= | Silent (SNP) | VAF 11/143 reads (8%) | called by muse, mutect2
- UGT2B10 | c.498C>A p.P166= | Silent (SNP) | VAF 62/247 reads (25%) | called by muse, mutect2, varscan2
- XKR6 | c.1398G>A p.P466= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs552864192, COSV58657541; called by muse, mutect2, varscan2
- ZNF493 | c.189T>C p.F63= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs190608187, COSV62749955; called by muse, mutect2, varscan2
- ZNRF4 | c.153C>A p.A51= | Silent (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- ASB5 | c.197-16122A>C | Intron (SNP) | VAF 22/92 reads (24%) | called by muse, mutect2, varscan2
- ATP2B2 | c.*188C>A | 3'UTR (SNP) | VAF 32/126 reads (25%) | called by muse, mutect2, varscan2
- IL32 | c.253-21C>T | Intron (SNP) | VAF 29/113 reads (26%) | catalogued as rs1462385255; called by muse, mutect2, varscan2
- MEFV | c.910+2144G>A | Intron (SNP) | VAF 8/43 reads (19%) | catalogued as rs775884552; called by mutect2, varscan2
- MUC19 | n.23208C>A | RNA (SNP) | VAF 8/86 reads (9%) | called by mutect2, varscan2
- OPA3 | c.*40G>A | 3'UTR (SNP) | VAF 9/173 reads (5%) | called by muse, mutect2
- PET100 | c.138+31T>A | Intron (SNP) | VAF 57/177 reads (32%) | called by muse, mutect2, varscan2
- RAPSN | c.1166+19del | Intron (DEL) | VAF 7/28 reads (25%) | catalogued as rs760797252; called by mutect2, pindel, varscan2
- STK40 | c.1089+66G>C | Intron (SNP) | VAF 67/241 reads (28%) | catalogued as COSV63734738; called by muse, mutect2, varscan2
